Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GM, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GM-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: moderate differentiated adenocarcinoma located in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: maximal diameter 4 cm

Lymph node status: 13 lymph nodes, of which 2 contain tumor

Any comments or amendments: radical resection

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal C15.5
QW 1/29/14

Source: NCI Genomic Data Commons file d1e2b356-5c09-4800-82f1-4793be87b881 (TCGA-2H-A9GM.92FD2446-E537-4194-B436-260954F5D66C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).